Somatic mutation profile of tumor specimen TARGET-50-PALGLU-01A (aliquot TARGET-50-PALGLU-01A-01D) from TARGET case TARGET-50-PALGLU, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.5 years (1,275 days).
Specimen TARGET-50-PALGLU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 729156c8-dc37-4737-9b1f-33f3bd22180f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PALGLU-10A (Blood Derived Normal), aliquot TARGET-50-PALGLU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6c7ac558-5918-4bb3-be00-1ec9f349d7ed

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCC | c.1916T>G p.I639S | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59096772; called by muse, mutect2, varscan2
- SLC27A5 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757190701, COSV54019579; called by muse, mutect2, varscan2
- FASN | c.6279G>A p.E2093= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs1205548680; called by muse, mutect2
